Somatic mutation profile of tumor specimen TCGA-C4-A0F1-01A (aliquot TCGA-C4-A0F1-01A-11D-A10S-08) from TCGA case TCGA-C4-A0F1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 71.7 years (26,178 days).
Specimen TCGA-C4-A0F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0597b51c-23b7-461c-a78c-65d5743c0551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C4-A0F1-10A (Blood Derived Normal), aliquot TCGA-C4-A0F1-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db141073-789e-4bd3-9318-f18c51063ec6

The open-access MAF lists 192 somatic variants for this specimen: 131 protein-altering or splice-affecting, 58 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 58, Nonsense Mutation 13, Intron 1, 3'UTR 1, Translation Start Site 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.15095G>A p.G5032E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67997095; called by muse, mutect2, varscan2
- AFTPH | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV53222752; called by muse, mutect2, varscan2
- AGFG2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 36/149 reads (24%) | catalogued as COSV53544621; called by muse, mutect2, varscan2
- AMER1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 47/91 reads (52%) | catalogued as rs1373608390, COSV57659499; called by muse, mutect2, varscan2
- ANK2 | c.647A>G p.H216R | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52194394; called by muse, mutect2, varscan2
- AP2S1 | c.6C>T p.I2= | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as rs977983196, COSV54384629, COSV99617353; called by muse, mutect2, varscan2
- API5 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV66635506; called by muse, mutect2, varscan2
- APOB | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51957687; called by muse, mutect2, varscan2
- APOB | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895052788, COSV51943291, COSV51957701; called by muse, mutect2, varscan2
- ATG7 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV61612497; called by muse, mutect2, varscan2
- ATN1 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV63113399; called by muse, mutect2, varscan2
- BIRC5 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV56958298; called by muse, mutect2, varscan2
- BOD1L1 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50097029; called by muse, mutect2, varscan2
- BUB1B | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV55011338; called by muse, varscan2
- CDH3 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1242553513, COSV50582326; called by muse, mutect2, varscan2
- CELF4 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV58469204; called by muse, mutect2, varscan2
- CELSR2 | c.5120G>A p.G1707E | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.113); catalogued as COSV54780973; called by muse, varscan2
- CELSR2 | c.5254G>A p.G1752S | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as rs1050401849, COSV54780983, COSV99604740; called by muse, varscan2
- CELSR3 | c.1252A>T p.M418L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as COSV51179791; called by muse, mutect2, varscan2
- CFAP206 | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51537868, COSV51538273; called by muse, mutect2, varscan2
- CILP | c.1257G>C p.Q419H | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56028747; called by muse, mutect2, varscan2
- CPEB1 | c.202G>C p.E68Q (on ENST00000617958; = p.E8Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV71604651, COSV71605035; called by muse, mutect2, varscan2
- CREBBP | c.4990C>T p.R1664C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52114474; called by muse, mutect2, varscan2
- CRX | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370592248; called by muse, mutect2, varscan2
- CSKMT | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs375107020, COSV63473147; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- DCAF6 | c.2278G>C p.D760H (on ENST00000312263 / NM_001349778.1; = p.D780H on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56586932; called by muse, mutect2, varscan2
- DENR | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV54889652; called by muse, mutect2, varscan2
- DHX36 | c.1225C>G p.P409A | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV57671285, COSV57678136; called by muse, mutect2, varscan2
- DISP3 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV53839716; called by muse, mutect2, varscan2
- DUSP29 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.49); catalogued as rs956170734, COSV58301665; called by muse, mutect2, varscan2
- EGF | c.1611G>C p.E537D | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54486099; called by muse, mutect2, varscan2
- EGFLAM | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs746669041, COSV59298727; called by muse, mutect2, varscan2
- EIF3A | c.3059G>A p.R1020Q | Missense Mutation (SNP) | VAF 93/324 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV64961867; called by muse, mutect2, varscan2
- EZH1 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV70551090; called by muse, mutect2, varscan2
- FAM193A | c.2811G>C p.K937N | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61199790; called by muse, mutect2, varscan2
- FJX1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100502797, COSV58553013; called by muse, mutect2, varscan2
- FOXM1 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs1159130429, COSV61207892; called by muse, mutect2, varscan2
- GALNT5 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV52042166; called by muse, mutect2, varscan2
- GLB1 | c.1746G>T p.W582C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM115629, COSV56568868; called by muse, mutect2, varscan2
- GRIA1 | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414317069, COSV53609464; called by muse, mutect2, varscan2
- GRID2 | c.2606A>G p.D869G | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56284042; called by muse, varscan2
- GTSE1 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs528775411, COSV71890079; called by muse, mutect2, varscan2
- HDAC6 | c.3040G>T p.G1014W | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV61929683, COSV61931011; called by muse, mutect2
- HEPHL1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1333071104, COSV59897788; called by muse, mutect2, varscan2
- HNF4G | c.349-1G>A p.X117_splice (on ENST00000354370 / NM_001330561.2; = p.X164_splice on NM_004133.5) | Splice Site (SNP) | VAF 20/90 reads (22%) | catalogued as COSV62968760; called by muse, varscan2
- HRNR | c.381T>A p.F127L | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64263737; called by muse, mutect2, varscan2
- IL6ST | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV100411089, COSV61143317; called by muse, mutect2, varscan2
- INO80 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV62743479; called by muse, mutect2, varscan2
- INPP1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59417961; called by muse, mutect2, varscan2
- IRF7 | c.1412G>T p.C471F (on ENST00000397566; = p.C458F on NM_001572.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52764441; called by muse, mutect2, varscan2
- KCNH8 | c.1730A>G p.Y577C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60480137; called by muse, mutect2, varscan2
- KCNS3 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1398464477, COSV58409222; called by muse, mutect2, varscan2
- KIF18A | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54188320; called by muse, mutect2, varscan2
- KLHDC4 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54511894; called by muse, mutect2, varscan2
- KMT2A | c.9838C>T p.R3280* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV63282766; called by muse, mutect2, varscan2
- KMT2B | c.5059G>A p.D1687N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as COSV55871267; called by muse, mutect2, varscan2
- KMT2C | c.11620G>T p.E3874* | Nonsense Mutation (SNP) | VAF 112/427 reads (26%) | catalogued as COSV100073790; called by muse, mutect2, varscan2
- KMT2C | c.10600C>T p.Q3534* | Nonsense Mutation (SNP) | VAF 54/162 reads (33%) | catalogued as rs759394420, COSV100073792; called by muse, mutect2, varscan2
- KMT2D | c.13903C>T p.Q4635* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as CM138451, COSV56467295; called by muse, mutect2, varscan2
- LAMB2 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs888403715, COSV59738785; called by muse, mutect2, varscan2
- LILRB3 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs774562400; called by muse, mutect2, varscan2
- LRRN1 | c.1240T>A p.L414I | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV60017134; called by muse, mutect2, varscan2
- MAGEE1 | c.2514G>C p.L838F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63909115; called by muse, mutect2, varscan2
- MAGI2 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62706252; called by muse, mutect2, varscan2
- MDN1 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV65516979, COSV65532359; called by muse, mutect2, varscan2
- MED15 | c.1951G>A p.G651S (on ENST00000263205 / NM_001003891.3; = p.G611S on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147995933, COSV53026493; called by muse, mutect2, varscan2
- MERTK | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV54937198; called by muse, mutect2, varscan2
- MIA3 | c.4288G>C p.D1430H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV60519315; called by muse, mutect2, varscan2
- MINDY2 | c.1781C>G p.S594C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV57509163; called by muse, varscan2
- MINPP1 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV64355791; called by muse, mutect2, varscan2
- MLH1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs587779008, CM093752, HD971451, COSV51613919, COSV51625788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOGAT1 | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV71480182; called by muse, mutect2, varscan2
- MSH5 | c.1715C>A p.T572N | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV65212060; called by muse, varscan2
- MTPAP | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs570052537, COSV53936894; called by muse, mutect2, varscan2
- MYH1 | c.227A>C p.Q76P | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV55450917; called by muse, mutect2, varscan2
- NBEA | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100084690; called by muse, mutect2, varscan2
- NID1 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV51630547; called by muse, mutect2, varscan2
- NIN | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV55390617, COSV55409846; called by muse, mutect2, varscan2
- OR8B4 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV62069791; called by muse, mutect2, varscan2
- OR8K3 | c.915T>A p.N305K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1448905021, COSV57133503; called by muse, mutect2, varscan2
- PCLO | c.9370del p.A3124Lfs*4 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV61616390; called by mutect2, pindel, varscan2
- PDK2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV50303251, COSV50305410; called by muse, varscan2
- PHIP | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51512229; called by muse, mutect2, varscan2
- PKD1 | c.7804C>T p.Q2602* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as CM123947; called by muse, mutect2, varscan2
- PLCD3 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59563635; called by muse, mutect2, varscan2
- PPIP5K2 | c.3439C>T p.L1147F (on ENST00000358359 / NM_001276277.3; = p.L1126F on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV58610762; called by muse, mutect2, varscan2
- RESF1 | c.4325G>A p.R1442K | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as rs1330465984, COSV57026609; called by muse, mutect2, varscan2
- RFESD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV57225253; called by muse, varscan2
- RNF216 | c.2326G>C p.E776Q (on ENST00000425013 / NM_207116.3; = p.E833Q on NM_207111.4) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV66293154; called by muse, mutect2, varscan2
- RPL26 | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV53447758, COSV99549481; called by muse, mutect2, varscan2
- RSRC2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs1193679923, COSV59207085; called by muse, mutect2, varscan2
- SEMA6B | c.1133G>C p.C378S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56706504; called by muse, mutect2, varscan2
- SGO1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1460936895, COSV55425567; called by muse, mutect2, varscan2
- SLC16A14 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54618211; called by muse, mutect2, varscan2
- SLC38A6 | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV50787264; called by muse, mutect2, varscan2
- SMOC1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs199928475, COSV62763868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMOC2 | c.1300G>A p.A434T (on ENST00000356284 / NM_001166412.2; = p.A445T on NM_022138.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62445608; called by muse, mutect2, varscan2
- SRPRB | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 241/432 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV71749307; called by muse, mutect2, varscan2
- STRA8 | c.286C>A p.H96N (on ENST00000275764; = p.H74N on NM_182489.2) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV51963692, COSV99312248; called by muse, mutect2, varscan2
- SUCNR1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 156/290 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV62912831; called by muse, mutect2, varscan2
- SYNE1 | c.14924G>C p.G4975A (on ENST00000367255 / NM_182961.4; = p.G4904A on NM_033071.3) | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55131202; called by muse, mutect2, varscan2
- TBXAS1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV54956135; called by muse, mutect2, varscan2
- TCF25 | c.1812C>G p.I604M | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as COSV54533246; called by muse, mutect2, varscan2
- THEMIS2 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1244614530, COSV61078613; called by muse, mutect2, varscan2
- TLE3 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1350882604, COSV58176062; called by muse, mutect2, varscan2
- TLR10 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1201664038, COSV58302745; called by muse, mutect2, varscan2
- TMEM117 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896173, COSV56921533; called by muse, mutect2, varscan2
- TP53I3 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1165133175, COSV53188938; called by muse, mutect2, varscan2
- TP53TG5 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV65578426; called by mutect2, varscan2
- TRIM37 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV51889720; called by muse, mutect2, varscan2
- TRIP11 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV50974692; called by muse, mutect2, varscan2
- TSNARE1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs557067615, COSV56185661; called by muse, mutect2, varscan2
- TUBB2B | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1294933377, COSV52533308; called by muse, mutect2, varscan2
- UGT1A3 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.482); catalogued as rs776482922, COSV59401206; called by muse, mutect2, varscan2
- VCAN | c.3065G>A p.R1022K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV54119813; called by muse, mutect2, varscan2
- VIPR1 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs375826611; called by muse, mutect2, varscan2
- VWA3B | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.389); catalogued as COSV68243394; called by muse, mutect2, varscan2
- ZKSCAN1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs148037051; called by muse, mutect2, varscan2
- ZNF189 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52274934, COSV52277259; called by muse, mutect2, varscan2
- ZNF207 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100340287, COSV58302437; called by muse, mutect2, varscan2
- ZNF335 | c.1800G>C p.K600N | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59820937; called by muse, mutect2, varscan2
- ZNF790 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100764828, COSV63213534; called by muse, mutect2, varscan2
- ZSCAN5A | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV54232877; called by muse, mutect2, varscan2
- BEST1 | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- CDCA7L | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 60/215 reads (28%) | called by muse, mutect2, varscan2
- EIF5A | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- LIPC | c.1481C>G p.S494* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- RBM10 | c.2500A>T p.K834* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- USP13 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC1 | c.1137C>T p.L379= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs528197968, COSV60696368; called by muse, mutect2, varscan2
- ADA | c.237C>T p.I79= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV65741011; called by muse, mutect2
- ASF1A | c.357G>A p.E119= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV57649082; called by muse, mutect2, varscan2
- ATP13A2 | c.546C>T p.F182= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs780027766, CM081164, COSV58704602; called by muse, varscan2
- ATR | c.4692A>C p.I1564= | Silent (SNP) | VAF 54/232 reads (23%) | catalogued as COSV63394079; called by muse, mutect2, varscan2
- BPIFB4 | c.1828T>C p.L610= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs779361536, COSV64952647; called by muse, mutect2, varscan2
- C4BPA | c.1383C>T p.V461= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as rs773326982, COSV65537940; called by muse, mutect2, varscan2
- CACNA1S | c.978C>T p.L326= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV62944980; called by muse, mutect2, varscan2
- CAPN15 | c.2316C>T p.V772= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs1242363307, COSV54840124; called by muse, mutect2, varscan2
- CC2D2A | c.3282C>T p.L1094= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs766917693, COSV67504650; called by muse, mutect2, varscan2
- CCDC60 | c.771G>T p.V257= | Silent (SNP) | VAF 95/398 reads (24%) | catalogued as COSV59552411; called by muse, mutect2, varscan2
- CDON | c.108C>G p.L36= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV55003944; called by muse, mutect2, varscan2
- CELSR3 | c.1251G>A p.T417= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV50839820; called by muse, mutect2, varscan2
- CRYBB1 | c.189C>A p.V63= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV53235094, COSV99315885; called by muse, mutect2, varscan2
- CTTN | c.1614C>T p.Y538= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs545888686, COSV57237045; called by muse, mutect2, varscan2
- DGLUCY | c.1629G>A p.L543= | Silent (SNP) | VAF 49/182 reads (27%) | catalogued as rs779568190, COSV56371085; called by muse, mutect2, varscan2
- DNAH2 | c.8523G>A p.E2841= | Silent (SNP) | VAF 84/163 reads (52%) | catalogued as COSV66728928; called by muse, mutect2, varscan2
- DYRK4 | c.1371G>A p.T457= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs143171709; called by muse, mutect2, varscan2
- ENOX1 | c.216C>T p.I72= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV54922804; called by muse, mutect2, varscan2
- FLT1 | c.2859G>A p.K953= | Silent (SNP) | VAF 69/240 reads (29%) | catalogued as COSV56746556; called by muse, mutect2, varscan2
- FOCAD | c.267C>T p.L89= | Silent (SNP) | VAF 102/217 reads (47%) | catalogued as COSV58109198; called by muse, mutect2, varscan2
- GPR37 | c.327C>A p.P109= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV58260390; called by muse, mutect2, varscan2
- GPR68 | c.435C>T p.I145= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV53176353, COSV53176638; called by muse, mutect2, varscan2
- HDAC9 | c.2874C>G p.L958= | Silent (SNP) | VAF 72/226 reads (32%) | catalogued as COSV67787313; called by muse, mutect2, varscan2
- IGLV5-45 | c.126C>G p.T42= | Silent (SNP) | VAF 24/115 reads (21%) | called by muse, varscan2
- KIF2B | c.930G>A p.T310= | Silent (SNP) | VAF 71/149 reads (48%) | catalogued as rs139246128; called by muse, mutect2, varscan2
- LRRC4B | c.375C>T p.I125= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs1032387518, COSV65349655; called by muse, mutect2, varscan2
- MICALL1 | c.2007C>T p.I669= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as COSV53243993; called by muse, varscan2
- MICALL1 | c.2178C>T p.F726= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs1471972969, COSV53244006; called by muse, mutect2, varscan2
- MUC16 | c.30250C>T p.L10084= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV101198345, COSV101200803, COSV67502289; called by muse, mutect2, varscan2
- MYH2 | c.1320G>A p.L440= | Silent (SNP) | VAF 50/318 reads (16%) | catalogued as COSV55450924; called by muse, mutect2, varscan2
- NUSAP1 | c.798G>C p.L266= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52974083; called by muse, mutect2, varscan2
- OR10S1 | c.204C>G p.L68= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV73342644, COSV73342849, COSV73343087; called by muse, mutect2, varscan2
- OR4D1 | c.643C>T p.L215= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as COSV52126424; called by muse, mutect2, varscan2
- PHF19 | c.1659G>A p.E553= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as COSV65879205; called by muse, mutect2, varscan2
- PLD4 | c.840G>A p.Q280= | Silent (SNP) | VAF 75/250 reads (30%) | catalogued as COSV66915885; called by muse, mutect2, varscan2
- POLR3C | c.501G>A p.E167= | Silent (SNP) | VAF 33/235 reads (14%) | catalogued as COSV61937692; called by muse, mutect2, varscan2
- RBM10 | c.1713C>G p.T571= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV61313033; called by muse, mutect2, varscan2
- RBM12 | c.555C>A p.V185= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs1236794658, COSV58295862; called by muse, mutect2, varscan2
- RGP1 | c.921C>T p.L307= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV65240719; called by muse, mutect2, varscan2
- RGP1 | c.1014C>G p.L338= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV65240726; called by muse, mutect2, varscan2
- RIN2 | c.1050G>T p.T350= (on ENST00000255006 / NM_001242581.1; = p.T301= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs756921810, COSV54792856, COSV54795703; ClinVar: likely benign; called by muse, mutect2, varscan2
- SGSM2 | c.366C>T p.L122= | Silent (SNP) | VAF 116/251 reads (46%) | catalogued as rs113450178; called by muse, mutect2, varscan2
- SH3BP4 | c.2844G>A p.L948= | Silent (SNP) | VAF 79/269 reads (29%) | catalogued as COSV60647191; called by muse, mutect2, varscan2
- SLC44A4 | c.885C>T p.F295= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs1459257644, COSV57669641; called by muse, mutect2, varscan2
- SNAPC4 | c.2535C>G p.L845= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV53738858; called by muse, mutect2, varscan2
- SPOCD1 | c.1944C>A p.L648= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV57100921; called by muse, mutect2, varscan2
- SRRM2 | c.3450G>A p.S1150= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as rs1476353028, COSV57072670; called by muse, mutect2, varscan2
- SYNGR2 | c.447C>T p.I149= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV56746900; called by muse, mutect2, varscan2
- TINAGL1 | c.279C>T p.L93= | Silent (SNP) | VAF 70/257 reads (27%) | catalogued as rs769087943, COSV54700233; called by muse, mutect2, varscan2
- TPGS2 | c.243G>A p.V81= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV57541942; called by muse, mutect2, varscan2
- TTLL2 | c.1617G>A p.P539= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as rs758899568, COSV53446352; called by muse, mutect2
- UPP2 | c.798C>G p.L266= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV50050357, COSV99134828; called by muse, mutect2, varscan2
- VCAM1 | c.939T>C p.F313= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV54122959; called by muse, mutect2, varscan2
- VPS13B | c.3021G>A p.K1007= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs1043986535, COSV100660889, COSV62161015; called by muse, mutect2, varscan2
- ZBTB21 | c.288G>A p.K96= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1177439426, COSV60406206; called by muse, mutect2, varscan2
- ZMYM3 | c.945G>A p.R315= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV58741381; called by muse, mutect2, varscan2
- ZNF517 | c.1335C>T p.L445= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV63465493; called by muse, mutect2, varscan2
- MASP1 | c.1303+5252C>T | Intron (SNP) | VAF 136/228 reads (60%) | catalogued as COSV99962514; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 18/56 reads (32%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- UVSSA | c.*9260G>T | 3'UTR (SNP) | VAF 35/316 reads (11%) | catalogued as COSV61352102; called by muse, varscan2
